Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A8N1, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A8N1-01A (Primary Tumor).

[page 1 of 3]
Sex: Male

Printed :

Page 1 of 2

Lab #:

26. C¹ TCD 6-3
Adenocarcinoma, diffuse type 8/45/3
Adenocarcinoma, intestinal type 8/44/3
Site: Body & stomach Clb. 2

Antral carcinoma.

MACROSCOPIC DESCRIPTION

Specimen container labelled "gastrectomy": A proximal gastrectomy specimen, 75mm along the lesser curvature, 145mm along the greater curvature, 27mm in diameter of the proximal staple end and 45mm of the distal staple end, together with a lesser omentum 100x110x15mm as well as a greater omentum 320x160x20mm. The gastric cavity has been opened previously along the lesser curvature to reveal a large centrally ulcerated edge - raised tumour approximately 55x45mm, which is located along the greater curvature of the body, about 50mm from the proximal end and 55mm from the distal end and has on cut surface infiltrated the full thickness of the gastric wall, showing maximal tumour thickness of 18mm.

Blocks selected: (a- both proximal (large) and distal (smaller) resection margin, b- tumour and the adjacent proximal normal gastromucosa, c- the tumour and adjacent distal normal gastric mucosa, d- further section of the tumour showing maximal tumour thickness, e- the non neoplastic gastric mucosa from both lesser curvature and greater curvature, f- all the small lesser curvature nodes, g,h & i - gastric lymph node along the greater curvature, j- probable small lymph node within the omental fat)

Registrar/Typist:

MICROSCOPIC DESCRIPTION

Sections of the main tumour mass show a solid structureless tumour with mass with thin fibrous septa. There is full thickness invasion of stomach wall into adventitial fat. At the periphery and at metastatic sites the tumour shows moderately differentiated glandular acini. No signet ring cells are seen. The appearance is consistent with an intestinal type tumour.

No nodes are seen on the lesser curve. 10/17 nodes taken from the greater curve show tumour. Tumour is seen in adventitial fat, apparently separate from lymph nodes. Tumour is seen in lymphatics and is present in lymphatics at the distal margin. No tumour is seen in omentum.

Sections of the gastric mucosa show a severe chronic gastritis. No

[page 2 of 3]
DOB:

Sex: Male

Anatomical Pathology

Page 2 of 2

Helicobacter are seen. There is mild focal intestinal metaplasia. Dysplasia is seen in deep gastric glands but not surface foveolar epithelium.

PATHOLOGIST'S OPINION

Stomach - Poor differentiated intestinal type adenocarcinoma with full thickness invasion of stomach wall, lymphatic involvement, 10/17 lymph nodes involved and tumour at distal margin.

Registrar/Typist:

Pathologist:

*Per TSS, dx discrepancy from
Statis TCGA tumor to be
adenocarcinoma, diffuse type. BCR*

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	adenocarcinoma, intestinal type	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	adenocarcinoma, diffuse type.	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	After pathology review of top slide from frozen tissue, the diagnosis was found to be of intestinal diffuse subtype.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist

Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 4f366bb6-1c21-4c45-bc5c-ecea9a52be21 (TCGA-RD-A8N1.76DF68C7-C8FE-48B0-803C-2AA2FA08A691.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).